Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3319, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3319-01A (Primary Tumor).

[page 1 of 2]
Laboratory Patient Report
Print Date/Time:

Surgical Pathology

Histopathological Examination

Path#:
Collected: Received: Complete:

Pre-Op Diagnosis : Left Renal Tumor

Order Physician

Specimens : Kidney, Left
Adrenal Gland, Left
Spleen

Frozen Diagnosis :

Report

: GROSS EXAMINATION:

A. The specimen is received in a container labeled with the name of the patient and labeled as kidney, left. The specimen consists of a kidney and attached perinephric fat which measures en bloc 21 x 15 x 8 cm and weighs 930 g. The ureter and vascular margins of resection are submitted in block 1. The kidney stripped of fat measures 11 x 7 x 5 cm and weighs 184 g. Sectioning into the kidney shows a few large cortical cysts measuring up to 4.5 cm and an oval golden yellow focally hemorrhagic mass measuring 6.0 x 3.0 x 2.5 cm. The mass bulges against the capsule but is not grossly adherent to the capsule. A section of the capsule overlying the mass is submitted in block 2. Sections of the mass are submitted in blocks 3-7. The pelvis and calices are not grossly dilated. The cortex averages 0.8 cm. A random section of kidney is submitted in block 8. Sections from the cortical cysts are submitted in block 9. Sectioning through the attached fat shows a portion of adrenal gland which measures 6.0 x 2.5 x 1.0 cm. Sectioning through the adrenal shows no discrete masses. Representative sections are submitted in blocks 10-12.

B. The specimen is received in a container labeled with the name of the patient and labeled as adrenal gland, left. The specimen consists of an irregular piece of yellow fibrofatty tissue measuring 4.2 x 2.0 x 1.2 cm. Sectioning through the specimen shows a portion of adrenal gland measuring 2.0 cm. Representative sections are submitted.

C. The specimen is received in a container labeled with the name of the patient and labeled as spleen. The specimen consists of a 209 g spleen which measures 10.0 x 7.0 x 5.5

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

[page 2 of 2]
cm. Approximately 5% of the capsule is disrupted.
Sectioning through the spleen shows no discrete masses.
Representative sections are submitted. [REDACTED]

CHECKLIST:

KIDNEY: Nephrectomy, radical
SPECIMEN TYPE: Radical nephrectomy
LATERALITY: Left
TUMOR SITE: Mid lower pole
FOCALITY: Unifocal
TUMOR SIZE (LARGEST TUMOR IF MULTIPLE): 6.0 x 3.0 x 2.5 cm
MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney
HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma
HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): G2: Nuclei
slightly irregular, approximately 15 microns; nucleoli
evident.
EXTENT OF INVASION
PRIMARY TUMOR (PT): pT1b: Tumor more than 4 cm but not more
than 7 cm in greatest dimension, limited to kidney
REGIONAL LYMPH NODES (PN): pNX: Cannot be assessed
DISTANT METASTASIS (PM): pMX: Cannot be assessed
MARGINS: Uninvolved by invasive carcinoma
ADRENAL GLAND: Uninvolved by tumor (see specimen B)
VENOUS (LARGE VESSEL) INVASION (V): Present
LYMPHATIC (SMALL VESSEL) INVASION (L): Absent
ADDITIONAL PATHOLOGIC FINDINGS: Cortical cysts.
Moderate arterial and arteriolonephrosclerosis.
[T-71000 M-83103 189.0 P3-44070]
PATHOLOGIC STAGE SUMMARY: pT1bNXMXG2

Intradepartmental consultation obtained.

B. Left adrenal gland (resection): Mild nodular cortical
hyperplasia.
No carcinoma identified.
[T-B3000 M-09410 V71.1 P3-44070]

C. Spleen (splenectomy): Focal capsular disruption and fresh
hemorrhage.
Negative for tumor.

[T-C3000 M-14400 289.59 P3-44050]

[REDACTED]

Electronically Signed by:

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 02c3af5e-2141-4c13-b261-67ee7ea8193d (TCGA-A3-3319.ADB27F4A-D8EC-458B-A936-0AB0DA1D2091.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).